Somatic mutation profile of tumor specimen TCGA-AF-A56K-01A (aliquot TCGA-AF-A56K-01A-32D-A38X-10) from TCGA case TCGA-AF-A56K, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectosigmoid junction; AJCC pathologic stage: Stage IIA; Age at diagnosis: 56.2 years (20,527 days).
Specimen TCGA-AF-A56K-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b7fd4b5d-d67d-4854-8368-2f5ca87bf65a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AF-A56K-10A (Blood Derived Normal), aliquot TCGA-AF-A56K-10A-01D-A38X-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/afd044b5-9f59-4523-9fea-696050cb7621

The open-access MAF lists 97 somatic variants for this specimen: 74 protein-altering or splice-affecting, 21 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 59, Silent 21, Nonsense Mutation 11, In Frame Del 2, RNA 2, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NEB | c.17386C>T p.R5796* | Nonsense Mutation (SNP) | VAF 14/103 reads (14%) | catalogued as rs760935667, CM1413906, COSV50882267; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.1024C>T p.R342* | Nonsense Mutation (SNP) | VAF 52/90 reads (58%) | hotspot (GDC flag); catalogued as rs730882029, CM004908, COSV52665487; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AATK | c.1612G>A p.A538T (on ENST00000326724 / NM_001080395.3; = p.A435T on NM_004920.2) | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as rs747864469, COSV100353207; called by muse, mutect2, varscan2
- ABCA13 | c.9788T>A p.F3263Y | Missense Mutation (SNP) | VAF 26/150 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV71284892; called by muse, varscan2
- ABCB11 | c.2203G>T p.E735* | Nonsense Mutation (SNP) | VAF 9/101 reads (9%) | catalogued as COSV55587613; called by muse, mutect2
- ADAD1 | c.50C>T p.A17V | Missense Mutation (SNP) | VAF 7/147 reads (5%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.86); catalogued as COSV56641601; called by muse, mutect2
- ANTXR1 | c.661A>G p.I221V | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.705); catalogued as COSV100363024; called by muse, mutect2, varscan2
- APC | c.3493A>T p.K1165* | Nonsense Mutation (SNP) | VAF 47/88 reads (53%) | catalogued as COSV57326930, COSV57341138; called by muse, mutect2, varscan2
- ARAP3 | c.1504C>T p.R502W | Missense Mutation (SNP) | VAF 17/98 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as rs976476927, COSV53348668; called by muse, mutect2, varscan2
- ARHGEF17 | c.3670C>A p.L1224M | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99736652; called by muse, mutect2, varscan2
- ASTL | c.784G>A p.G262S | Missense Mutation (SNP) | VAF 48/162 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753364550, COSV60904210; called by muse, mutect2
- ATP2B2 | c.73G>A p.G25R | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); catalogued as rs765743831, COSV100660416; called by muse, mutect2, varscan2
- CA10 | c.49G>A p.V17I | Missense Mutation (SNP) | VAF 12/95 reads (13%) | SIFT tolerated (0.71); PolyPhen benign (0.02); catalogued as rs756317806, COSV53340059; called by muse, mutect2, varscan2
- CCDC157 | c.395C>T p.T132M | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as rs542834702, COSV57838151; called by muse, mutect2, varscan2
- CCDC73 | c.325C>A p.Q109K | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.168); catalogued as COSV58796686; called by muse, mutect2, varscan2
- CD163 | c.1744G>T p.E582* | Nonsense Mutation (SNP) | VAF 16/75 reads (21%) | catalogued as COSV100776082, COSV63130696; called by muse, mutect2, varscan2
- CDK11B | c.544C>T p.R182W | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.716); catalogued as COSV100477464; called by muse, mutect2, varscan2
- CNOT1 | c.1678A>G p.I560V | Missense Mutation (SNP) | VAF 49/101 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100409972; called by muse, mutect2, varscan2
- COL22A1 | c.3427G>T p.E1143* | Nonsense Mutation (SNP) | VAF 10/66 reads (15%) | catalogued as COSV100280555; called by muse, mutect2, varscan2
- DENND2B | c.2249C>G p.A750G | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.241); catalogued as COSV58202158; called by muse, mutect2, varscan2
- DIO2 | c.770G>T p.W257L | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.824); catalogued as COSV70444955; called by muse, mutect2, varscan2
- DTNA | c.547G>T p.E183* | Nonsense Mutation (SNP) | VAF 43/87 reads (49%) | catalogued as COSV99314995; called by muse, mutect2, varscan2
- EPHA6 | c.3155C>T p.P1052L | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.284); catalogued as rs778168979, COSV67558533; called by muse, mutect2, varscan2
- ERBB4 | c.1598T>C p.I533T | Missense Mutation (SNP) | VAF 14/314 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.259); catalogued as rs1046844409, COSV99631696; called by muse, mutect2
- FAM181A | c.808G>A p.V270I | Missense Mutation (SNP) | VAF 26/39 reads (67%) | SIFT deleterious (0.05); PolyPhen benign (0.127); catalogued as rs368140620, COSV50888168; called by muse, mutect2, varscan2
- FER1L6 | c.1887G>T p.M629I | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV101206158; called by muse, varscan2
- FOXJ2 | c.1244G>A p.C415Y | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99368919; called by muse, mutect2, varscan2
- GALNT14 | c.1459C>A p.P487T | Missense Mutation (SNP) | VAF 36/96 reads (38%) | SIFT tolerated (0.65); PolyPhen benign (0.348); catalogued as rs1296632084, COSV100205491; called by muse, mutect2, varscan2
- GLIS1 | c.1610C>A p.A537E | Missense Mutation (SNP) | VAF 19/100 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.075); catalogued as COSV100390770; called by muse, mutect2, varscan2
- GPT2 | c.409C>T p.R137W | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as rs768172166, COSV100413055; called by muse, mutect2, varscan2
- IGSF10 | c.6678C>A p.Y2226* | Nonsense Mutation (SNP) | VAF 4/74 reads (5%) | catalogued as COSV99193743; called by muse, mutect2
- MEGF10 | c.881G>T p.G294V | Missense Mutation (SNP) | VAF 69/148 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); catalogued as COSV99175522; called by muse, mutect2, varscan2
- MEGF11 | c.2021C>T p.T674I | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV99989080; called by muse, mutect2, varscan2
- MFSD13A | c.251+1G>A p.X84_splice | Splice Site (SNP) | VAF 7/49 reads (14%) | catalogued as COSV99488028; called by muse, mutect2, varscan2
- NCF1 | c.1009C>T p.R337C | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.571); catalogued as COSV99194317; called by muse, mutect2, varscan2
- NFE2L2 | c.1040C>T p.S347L | Missense Mutation (SNP) | VAF 20/248 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV67960649; called by muse, mutect2
- NOP58 | c.200A>C p.K67T | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.074); catalogued as COSV99970816; called by muse, mutect2, varscan2
- NPTX1 | c.205_207del p.K69del | In Frame Del (DEL) | VAF 6/40 reads (15%) | catalogued as rs1272692349; called by mutect2, pindel
- NUDT17 | c.895C>T p.P299S | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); catalogued as COSV100566850; called by muse, mutect2, varscan2
- OR10H1 | c.300G>T p.Q100H | Missense Mutation (SNP) | VAF 26/100 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100612488; called by muse, mutect2, varscan2
- OR12D3 | c.364G>A p.V122I | Missense Mutation (SNP) | VAF 30/166 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.303); catalogued as COSV101011453; called by muse, mutect2, varscan2
- OR1E2 | c.760C>A p.L254I | Missense Mutation (SNP) | VAF 16/188 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.558); catalogued as COSV99943501; called by muse, mutect2
- OR6C65 | c.64C>A p.Q22K | Missense Mutation (SNP) | VAF 23/129 reads (18%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.039); catalogued as COSV101110208, COSV99059231; called by muse, mutect2, varscan2
- PAN3 | c.685C>G p.R229G | Missense Mutation (SNP) | VAF 28/140 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as COSV101111174; called by muse, mutect2, varscan2
- PCDHB6 | c.661C>T p.R221W | Missense Mutation (SNP) | VAF 64/112 reads (57%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.9); catalogued as rs781793464, COSV50701880, COSV50734398; called by muse, mutect2, varscan2
- PCDHGA6 | c.301C>T p.R101W | Missense Mutation (SNP) | VAF 35/100 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.052); catalogued as rs781113576, COSV99539028; called by muse, mutect2, varscan2
- PDILT | c.1090C>T p.R364C | Missense Mutation (SNP) | VAF 15/118 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.625); catalogued as rs191618493; called by muse, mutect2, varscan2
- PLEC | c.7484C>T p.A2495V (on ENST00000322810 / NM_201380.4; = p.A2385V on NM_000445.5) | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); catalogued as rs782367691, COSV59616245; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PMFBP1 | c.802G>A p.A268T | Missense Mutation (SNP) | VAF 37/83 reads (45%) | SIFT tolerated (0.19); PolyPhen benign (0.241); catalogued as rs758732718, COSV99401463; called by muse, mutect2, varscan2
- POM121 | c.3683C>T p.A1228V (on ENST00000434423; = p.A963V on NM_172020.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/334 reads (9%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.752); catalogued as rs377106663; called by muse, mutect2
- PXDN | c.1519A>G p.I507V | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT tolerated (0.31); PolyPhen benign (0.062); catalogued as rs1457099781, COSV99414776; called by muse, varscan2
- RAP1GAP | c.154G>A p.G52R | Missense Mutation (SNP) | VAF 24/38 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1444013165, COSV99265814; called by muse, mutect2, varscan2
- RARB | c.973G>T p.E325* (on ENST00000383772 / NM_001290216.2; = p.E318* on NM_000965.5 and 3 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 22/104 reads (21%) | catalogued as COSV51970098; called by muse, mutect2, varscan2
- RSF1 | c.3226C>T p.R1076* | Nonsense Mutation (SNP) | VAF 56/132 reads (42%) | catalogued as COSV100407860; called by muse, mutect2, varscan2
- RSF1 | c.20C>T p.A7V | Missense Mutation (SNP) | VAF 22/106 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.109); catalogued as COSV100407861; called by muse, mutect2, varscan2
- SACS | c.2734G>A p.D912N | Missense Mutation (SNP) | VAF 12/97 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs777238047, COSV66546239; called by muse, mutect2, varscan2
- SH3YL1 | c.325C>T p.R109C | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.787); catalogued as rs761115105, COSV100642247; called by muse, mutect2, varscan2
- SLC17A6 | c.206G>A p.R69H | Missense Mutation (SNP) | VAF 39/68 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.608); catalogued as rs1331584658, COSV99582266; called by muse, mutect2, varscan2
- SLC22A11 | c.527G>T p.C176F | Missense Mutation (SNP) | VAF 5/90 reads (6%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.827); catalogued as COSV100102649; called by muse, mutect2
- SLITRK6 | c.1048C>T p.R350C | Missense Mutation (SNP) | VAF 12/114 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.609); catalogued as rs200364181, COSV68389686; called by muse, mutect2, varscan2
- SNTG2 | c.312C>A p.F104L | Missense Mutation (SNP) | VAF 64/183 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.084); catalogued as rs372415553, COSV58008499; called by muse, mutect2, varscan2
- SNX2 | c.1364C>T p.A455V | Missense Mutation (SNP) | VAF 29/186 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.025); catalogued as rs757196187, COSV101075822; called by muse, mutect2, varscan2
- SOHLH2 | c.767T>C p.I256T | Missense Mutation (SNP) | VAF 33/202 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.011); catalogued as COSV101157988; called by muse, mutect2, varscan2
- SYCE1 | c.738G>T p.E246D (on ENST00000343131 / NM_001143764.3; = p.E210D on NM_130784.3) | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV58216436; called by muse, mutect2, varscan2
- SYT10 | c.857G>A p.R286H | Missense Mutation (SNP) | VAF 21/115 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.082); catalogued as rs146031713; called by muse, mutect2, varscan2
- TBX20 | c.157C>T p.Q53* | Nonsense Mutation (SNP) | VAF 22/223 reads (10%) | catalogued as COSV101282418; called by muse, mutect2, varscan2
- TFDP3 | c.920G>A p.G307E | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1469511193, COSV59539141; called by muse, mutect2, varscan2
- TIAM2 | c.1144C>T p.R382W | Missense Mutation (SNP) | VAF 41/211 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772490486, COSV100019220; called by muse, mutect2, varscan2
- TLN1 | c.3089C>T p.A1030V | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.371); catalogued as rs764011686, COSV100147362; called by muse, mutect2, varscan2
- TPO | c.1615A>T p.I539L | Missense Mutation (SNP) | VAF 28/97 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100221952; called by muse, mutect2, varscan2
- ZXDA | c.545C>T p.T182I | Missense Mutation (SNP) | VAF 16/138 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV62387703; called by muse, mutect2, varscan2
- LAMC1 | c.80_91del p.A27_A30del | In Frame Del (DEL) | VAF 6/43 reads (14%) | called by mutect2, varscan2
- PRKDC | c.1201_1204del p.D401Lfs*39 | Frame Shift Del (DEL) | VAF 16/86 reads (19%) | called by pindel, varscan2
- SGSM2 | c.2702A>G p.Q901R (on ENST00000426855 / NM_001098509.2; = p.Q946R on NM_014853.3) | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.58); called by muse, mutect2
- ABHD8 | c.120C>T p.P40= | Silent (SNP) | VAF 6/63 reads (10%) | catalogued as rs1227851623, COSV99395552; called by muse, mutect2, varscan2
- ATP8B2 | c.2886C>T p.P962= (on ENST00000672630; = p.P929= on NM_001367934.1 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 17/85 reads (20%) | catalogued as rs773791770, COSV100528209; called by muse, mutect2, varscan2
- BICC1 | c.1780C>T p.L594= | Silent (SNP) | VAF 179/410 reads (44%) | catalogued as rs769345651, COSV99570853; called by muse, mutect2, varscan2
- EGFLAM | c.2922G>T p.L974= (on ENST00000354891 / NM_001205301.2; = p.L966= on NM_152403.4) | Silent (SNP) | VAF 36/94 reads (38%) | catalogued as COSV100380722; called by muse, mutect2, varscan2
- FBXO41 | c.228G>A p.V76= | Silent (SNP) | VAF 18/43 reads (42%) | catalogued as COSV99721535; called by muse, mutect2, varscan2
- MN1 | c.3018G>A p.T1006= | Silent (SNP) | VAF 7/43 reads (16%) | catalogued as rs1055257417, COSV56556051; called by muse, mutect2, varscan2
- MUC16 | c.7872G>A p.T2624= | Silent (SNP) | VAF 22/189 reads (12%) | catalogued as rs773313432, COSV67444755; called by muse, mutect2, varscan2
- NGEF | c.1230C>T p.I410= | Silent (SNP) | VAF 22/286 reads (8%) | catalogued as COSV99890636; called by muse, mutect2
- NRXN1 | c.4374C>A p.P1458= | Silent (SNP) | VAF 8/79 reads (10%) | catalogued as COSV100640300, COSV60489707; called by muse, mutect2, varscan2
- NRXN1 | c.882C>T p.Y294= | Silent (SNP) | VAF 37/85 reads (44%) | catalogued as rs200464704, COSV58442569; ClinVar: benign / uncertain significance / likely benign; called by muse, mutect2, varscan2
- NRXN1 | c.453C>T p.S151= | Silent (SNP) | VAF 14/106 reads (13%) | catalogued as rs774821523, COSV68007971, COSV68052403; called by muse, mutect2, varscan2
- NTSR1 | c.600G>A p.A200= | Silent (SNP) | VAF 18/170 reads (11%) | catalogued as rs776251796, COSV100980711; called by muse, mutect2, varscan2
- PAPLN | c.432C>A p.G144= | Silent (SNP) | VAF 23/66 reads (35%) | catalogued as COSV99390367; called by muse, mutect2, varscan2
- PCDHB3 | c.1422C>T p.S474= | Silent (SNP) | VAF 20/49 reads (41%) | catalogued as rs782172125, COSV99166489; called by muse, mutect2, varscan2
- PCDHGB1 | c.1980C>T p.F660= | Silent (SNP) | VAF 38/68 reads (56%) | catalogued as COSV53918095; called by muse, mutect2, varscan2
- RAPGEFL1 | c.1260C>T p.I420= | Silent (SNP) | VAF 8/74 reads (11%) | catalogued as COSV99229222; called by muse, mutect2, varscan2
- RNF149 | c.1180C>A p.R394= | Silent (SNP) | VAF 57/231 reads (25%) | catalogued as COSV99766608, COSV99766784; called by muse, mutect2, varscan2
- SSPN | c.411G>T p.V137= | Silent (SNP) | VAF 9/51 reads (18%) | catalogued as COSV99658820; called by muse, mutect2, varscan2
- ST8SIA4 | c.54C>A p.I18= | Silent (SNP) | VAF 7/36 reads (19%) | catalogued as COSV51507997; called by muse, mutect2, varscan2
- VOPP1 | c.492G>A p.P164= | Silent (SNP) | VAF 25/228 reads (11%) | catalogued as rs534581582; called by muse, mutect2, varscan2
- ZC2HC1C | c.375T>C p.F125= | Silent (SNP) | VAF 19/96 reads (20%) | catalogued as COSV53172228; called by muse, mutect2, varscan2
- LINC00482 | n.912G>A | RNA (SNP) | VAF 9/36 reads (25%) | catalogued as rs1223684457; called by muse, mutect2, varscan2
- MIR518F | n.48G>C | RNA (SNP) | VAF 32/182 reads (18%) | called by muse, mutect2, varscan2
